CCDI case PBCRJW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/12ebc559-c264-4654-b15f-b6f7571c7bbd

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (4,999 days).

Biospecimens (3 samples)
- Sample 0DXCU1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXCUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DXCUJ: Tissue type: Tumor; Specimen type: Solid Tissue.
